Gene-level copy-number profile of tumor specimen C3L-01237-04 from CPTAC case C3L-01237, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 57.4 years (20,956 days).
Specimen C3L-01237-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 46ab5df5-f70e-4b01-904b-863ff4586a45.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01237-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/e5962001-e412-47cb-814f-233c285cbbb9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 103; copy number 1: 872; copy number 2: 22,941; copy number 3: 13,598; copy number 4: 15,578; copy number 5: 3,424; copy number 6: 1,219; copy number 7: 698; copy number 8: 6; copy number 9: 101; copy number 11: 79; copy number 12: 14; copy number 13: 10; copy number 14: 11; copy number 15: 122; copy number 16: 3; copy number 17: 1; copy number 19: 18; copy number 22: 1; copy number 25: 22; copy number 27: 10; copy number 35: 28; copy number 43: 26; copy number 44: 2; copy number 48: 2; copy number 55: 9; copy number 66: 3; copy number 72: 4; copy number 76: 5; copy number 83: 1.

Homozygous deletions (total copy number 0; autosomes only): 103 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,272,393–25,330,445, 2 genes (within-gene range 0–2): RHD, SDHDP6.
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–3): RNU6-904P, RPS16P3.
- chr3:75,629,993–90,261,708, 94 genes (broad region; genes not listed).
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr9:22,046,758–22,046,901, 1 gene (within-gene range 0–2): AL354709.1.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,819 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–16,536,172, 547 genes, copy number 5–13 (broad region; genes not listed).
- chr1:16,739,938–16,972,964, 3 genes, copy number 7 (within-gene range 3–7): AL021920.3, CROCC, CROCCP4.
- chr1:16,851,257–16,904,776, 9 genes, copy number 7: BX284668.1, BX284668.3, MIR3675, BX284668.2, RNU1-5P, BX284668.5, BX284668.4, RNU1-2, BX284668.6.
- chr2:45,164,816–45,612,165, 6 genes, copy number 7: LINC01121, AC093833.1, AC009236.2, AC009236.1, SRBD1, RN7SL414P.
- chr2:157,876,702–158,136,154, 1 gene, copy number 5 (within-gene range 4–5): UPP2.
- chr2:157,961,410–160,493,807, 45 genes, copy number 5: MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1, CCDC148, HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2, DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P, TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888, WDSUB1, BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2, PLA2R1, ITGB6, AC092153.1, LINC02478, RBMS1, MIR4785.
- chr3:154,827,016–154,861,017, 1 gene, copy number 5: AC073359.2.
- chr3:155,821,024–198,123,232, 734 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–67,169,595, 914 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:67,179,613–165,171,643, 1,613 genes, copy number 5 (broad region; genes not listed).
- chr5:167,116,318–181,342,213, 364 genes, copy number 5 (broad region; genes not listed).
- chr6:60,281,444–61,241,311, 7 genes, copy number 14–25: AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1.
- chr6:63,719,980–65,707,226, 1 gene, copy number 6 (within-gene range 4–25): EYS.
- chr6:64,377,795–87,155,285, 262 genes, copy number 6–19 (within-gene range 2–25) (broad region; genes not listed).
- chr7:52,269,437–64,150,721, 235 genes, copy number 5–83 (broad region; genes not listed).
- chr8:11,842,524–11,933,203, 4 genes, copy number 8: CTSB, AC025857.1, OR7E158P, OR7E161P.
- chr8:40,298,697–41,032,998, 6 genes, copy number 5–7: SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P.
- chr8:41,426,655–42,207,709, 26 genes, copy number 5: SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT.
- chr9:33,290,512–33,410,553, 4 genes, copy number 5: NFX1, Y_RNA, AQP7, AL356218.2.
- chr9:61,615,835–61,627,683, 1 gene, copy number 5: FAM242D.
- chr11:55,602,360–55,640,309, 2 genes, copy number 8: OR4C11, OR4P4.
- chr11:68,612,899–70,436,584, 54 genes, copy number 35–43 (within-gene range 2–43): AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:56,076,799–58,395,138, 131 genes, copy number 5 (broad region; genes not listed).
- chr12:61,600,067–62,279,150, 6 genes, copy number 6 (within-gene range 4–6): DUX4L52, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1.
- chr12:64,759,496–64,977,509, 1 gene, copy number 27 (within-gene range 4–27): AC078815.1.
- chr12:64,883,394–65,491,430, 12 genes, copy number 16–27 (within-gene range 2–27): LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60.
- chr12:67,131,567–70,637,440, 80 genes, copy number 11–19 (broad region; genes not listed).
- chr13:77,535,674–77,764,242, 7 genes, copy number 7: SCEL, AL137140.1, SCEL-AS1, RNY3P7, SPTLC1P5, SLAIN1, MIR3665.
- chr14:48,319,068–48,341,332, 2 genes, copy number 5: AL358335.3, RNU6-297P.
- chr16:31,355,134–31,603,531, 25 genes, copy number 5: ITGAX, AC093520.2, ITGAD, AC093520.1, COX6A2, AC026471.5, ZNF843, AC026471.4, AC026471.1, ARMC5, AC026471.6, TGFB1I1, SLC5A2, AC026471.3, RUSF1, AC026471.2, AHSP, LINC02190, AC106730.1, VN1R64P, VN1R65P, FRG2KP, AC106730.2, YBX3P1, ZNF720P1.
- chr16:50,246,137–54,158,512, 83 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr16:72,004,239–79,212,667, 153 genes, copy number 7–9 (within-gene range 1–9) (broad region; genes not listed).
- chr16:79,202,624–90,222,851, 309 genes, copy number 5–9 (broad region; genes not listed).
- chr19:15,737,985–15,836,328, 10 genes, copy number 7: OR10H3, CYP4F24P, AC004597.1, OR10H5, OR10H1, ZNF861P, AC004510.2, LINC01764, UCA1, AC004510.1.
- chr19:55,428,740–57,858,941, 144 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr19:57,849,859–57,865,117, 1 gene, copy number 6 (within-gene range 1–6): ZNF587.
- chr21:9,369,285–10,137,004, 14 genes, copy number 12: CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8.
- chr21:10,640,028–10,649,835, 2 genes, copy number 48: AF254982.1, IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 360. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
